Somatic mutation profile of tumor specimen 0DSG22 from CCDI case PBCHNH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 15.8 years (5,782 days).
Specimen 0DSG22: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d65b91c-8fde-4acb-9f11-e6a3ddbb90e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSG2J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbaf5cc0-6a6d-47fd-a32e-44d55e5c0c87

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, Silent 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 249/863 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- C2orf78 | c.1880G>A p.G627D | Missense Mutation (SNP) | VAF 87/551 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV68518901; called by muse, mutect2, varscan2
- COL20A1 | c.3376G>A p.G1126R | Missense Mutation (SNP) | VAF 34/533 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763684206; called by muse, mutect2
- GLYATL3 | c.621C>A p.D207E | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1290646818; called by muse, mutect2
- CPS1 | c.406T>G p.Y136D | Missense Mutation (SNP) | VAF 56/1259 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EYA3 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 37/546 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.035); called by muse, mutect2
- HAS1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2
- MAP7D2 | c.1178G>A p.G393D | Missense Mutation (SNP) | VAF 150/892 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MX2 | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NUDT3 | c.31A>C p.T11P | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PLEKHF1 | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TTN | c.11554C>T p.P3852S (on ENST00000591111; = p.P3806S on NM_003319.4) | Missense Mutation (SNP) | VAF 31/844 reads (4%) | called by muse, mutect2
- TYK2 | c.1594G>T p.A532S | Missense Mutation (SNP) | VAF 22/624 reads (4%) | SIFT tolerated (0.89); PolyPhen benign (0.083); called by muse, mutect2
- OR13C4 | c.72G>A p.E24= | Silent (SNP) | VAF 46/1019 reads (5%) | catalogued as COSV104373621; called by muse, mutect2
- TBC1D3F | c.825C>T p.D275= | Silent (SNP) | VAF 10/694 reads (1%) | catalogued as rs1451913083; called by muse, mutect2
- BGN | c.*17C>G | 3'UTR (SNP) | VAF 42/275 reads (15%) | called by muse, mutect2, varscan2
- MBD3 | c.500-44del | Intron (DEL) | VAF 14/147 reads (10%) | called by mutect2, varscan2
- PGM1 | c.247-5905C>T | Intron (SNP) | VAF 154/519 reads (30%) | called by muse, mutect2, varscan2
- RRAGB | c.*2C>T | 3'UTR (SNP) | VAF 32/697 reads (5%) | called by muse, mutect2
